Gene-level copy-number profile of tumor specimen TCGA-3H-AB3M-01A from TCGA case TCGA-3H-AB3M, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 53.4 years (19,503 days).
Specimen TCGA-3H-AB3M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.be171d25-cf67-411c-9c78-7acb6942b430.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3H-AB3M-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dbd226a4-a9f4-40eb-a4d8-37a50034539e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 20,903; copy number 2: 36,773; copy number 3: 2,063.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3H-AB3M-01A-11D-A39Q-01): tumor purity 0.83, ploidy 1.69, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:110,617,423–111,552,173, 7 genes (within-gene range 0–1): PITX2, LINC01438, MIR297, LYPLA1P2, AC004062.1, RNU6-289P, AC083795.1.
- chr4:121,118,299–121,696,995, 8 genes: AC105254.2, TNIP3, RNU6-948P, QRFPR, Y_RNA, AC093816.1, TUBB4BP5, ANXA5.
- chr9:21,231,266–22,029,594, 32 genes (within-gene range 0–1): IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr9:126,805,006–126,885,878, 2 genes: ZBTB43, ZBTB34.
- chr14:97,632,647–98,845,597, 11 genes: LINC02291, AL163872.1, LINC02312, AL355097.1, LINC01550, AL163932.1, LINC02295, RN7SL714P, AL132719.1, C14orf177, AL132796.1.
- chr16:6,380,476–6,395,578, 1 gene (within-gene range 0–1): AC006112.1.
- chr18:57,352,557–57,371,731, 1 gene: ST8SIA3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 20,854. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
